Somatic mutation profile of tumor specimen TCGA-ER-A42H-01A (aliquot TCGA-ER-A42H-01A-11D-A24R-08) from TCGA case TCGA-ER-A42H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.3 years (28,224 days).
Specimen TCGA-ER-A42H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7eafbf1-2926-48ee-89b4-9ea6b82cacf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A42H-10A (Blood Derived Normal), aliquot TCGA-ER-A42H-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20d893f0-ec09-4912-afcf-1b9bf8d3223c

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 39, Silent 17, Frame Shift Del 5, Nonsense Mutation 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, varscan2
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 173/178 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516792, CM071852, CM073191, COSV61068422, COSV61068985, COSV61070219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAT3 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs748493151, COSV100280270; called by muse, mutect2
- ARMCX5-GPRASP2 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 60/67 reads (90%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV100771768; called by muse, mutect2, varscan2
- ATP2B2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 124/225 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs370301558; called by muse, mutect2, varscan2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as COSV62562863; called by pindel, varscan2
- BEND6 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs760598916, COSV100876926; called by muse, mutect2, varscan2
- CDIP1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99566654; called by muse, mutect2
- CENPE | c.5679T>A p.N1893K | Missense Mutation (SNP) | VAF 76/80 reads (95%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV99478656; called by muse, mutect2, varscan2
- CHD9 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68299023; called by muse, mutect2, varscan2
- CPAMD8 | c.595G>A p.V199I (on ENST00000651564; = p.V152I on NM_015692.5) | Missense Mutation (SNP) | VAF 81/143 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs533642927, COSV99359064; called by muse, mutect2, varscan2
- DMTF1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs559006713, COSV58685724; called by muse, mutect2, varscan2
- GNAQ | c.188A>G p.H63R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681558; called by muse, mutect2, varscan2
- GPA33 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1446633231, COSV63300588; called by muse, mutect2, varscan2
- IQSEC1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1285176495, COSV56223381, COSV56224933; called by muse, mutect2, varscan2
- KIAA1328 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs775444735, COSV54448523; called by muse, mutect2, varscan2
- MAPK7 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.068); catalogued as COSV100219030; called by muse, mutect2, varscan2
- MARVELD2 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 47/104 reads (45%) | catalogued as COSV100347832; called by muse, mutect2, varscan2
- ME1 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100866616; called by muse, mutect2, varscan2
- MTIF3 | c.583_586del p.K195Efs*4 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs749040325; called by pindel, varscan2
- MUC16 | c.1436C>A p.P479Q | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV101200636; called by muse, mutect2, varscan2
- MYH3 | c.3145C>A p.L1049M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV99878594; called by muse, mutect2, varscan2
- NPEPL1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767087339, COSV61940066; called by muse, mutect2
- NRXN3 | c.851C>A p.T284N (on ENST00000557594 / NM_001272020.2; = p.T916N on NM_004796.6) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99820717, COSV99821406; called by muse, mutect2, varscan2
- PLA2G5 | c.72C>G p.D24E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100908263; called by muse, mutect2, varscan2
- PREPL | c.1907C>G p.S636* | Nonsense Mutation (SNP) | VAF 67/154 reads (44%) | catalogued as COSV99576359; called by muse, mutect2, varscan2
- PRR14 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV99788568; called by muse, mutect2, varscan2
- RBM34 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100784014; called by muse, mutect2
- RIC8A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100254883; called by muse, mutect2, varscan2
- SASS6 | c.1619C>A p.T540N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99790995; called by muse, mutect2, varscan2
- SEC11C | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100231084; called by muse, mutect2, varscan2
- SLC20A2 | c.466T>C p.F156L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100646157; called by muse, mutect2, varscan2
- SULF2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63420414; called by muse, mutect2, varscan2
- SYTL3 | c.1384C>T p.R462W (on ENST00000611299 / NM_001242394.1; = p.R394W on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs777596209, COSV99792330; called by muse, mutect2, varscan2
- TAF1L | c.4441C>T p.P1481S | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV99645152; called by muse, mutect2, varscan2
- UBAP2 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 23/24 reads (96%) | catalogued as rs369362609, COSV62547853; called by muse, mutect2, varscan2
- UNC13C | c.5408A>C p.Q1803P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV99521217; called by muse, mutect2
- USP13 | c.1879C>G p.P627A | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99831540, COSV99831667; called by muse, mutect2, varscan2
- USP20 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs537303607, COSV100204585; called by muse, mutect2, varscan2
- VPS4A | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV99652070; called by muse, mutect2, varscan2
- ZBBX | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536716722, COSV100284649; called by muse, mutect2, varscan2
- ZNF808 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 178/298 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100708118; called by muse, mutect2, varscan2
- ZNF862 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs765763911, COSV99783670; called by muse, mutect2, varscan2
- ZSWIM4 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1336472794, COSV54323524; called by muse, mutect2, varscan2
- SLC27A1 | c.253del p.V85* | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | called by mutect2, varscan2
- SUCLG1 | c.721_722del p.E241Nfs*16 | Frame Shift Del (DEL) | VAF 29/153 reads (19%) | called by mutect2, pindel, varscan2
- VIL1 | c.186_192del p.H63Gfs*25 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- ARID4B | c.3636C>T p.P1212= | Silent (SNP) | VAF 96/256 reads (38%) | catalogued as COSV99936044; called by muse, mutect2, varscan2
- BRF1 | c.1791T>C p.S597= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100527572; called by muse, mutect2, varscan2
- CCR3 | c.867C>T p.I289= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs770760041, COSV62462494; called by muse, mutect2, varscan2
- CES3 | c.1059C>A p.P353= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as COSV100310004; called by muse, mutect2, varscan2
- CNOT1 | c.5841G>A p.V1947= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV99800822; called by muse, mutect2, varscan2
- DAAM2 | c.516C>T p.R172= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV99226522; called by muse, mutect2
- DCDC2 | c.678C>T p.D226= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV101016722; called by muse, mutect2, varscan2
- GPBP1 | c.1335G>A p.P445= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as rs147297567; called by muse, mutect2, varscan2
- JAKMIP3 | c.877C>A p.R293= | Silent (SNP) | VAF 41/45 reads (91%) | catalogued as COSV100059585; called by muse, mutect2, varscan2
- LIPG | c.516G>C p.A172= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs574190987, COSV99724620; called by muse, mutect2, varscan2
- PLXNA4 | c.3939G>A p.P1313= | Silent (SNP) | VAF 24/223 reads (11%) | catalogued as rs377241563; called by muse, mutect2, varscan2
- PRKCG | c.27C>T p.G9= | Silent (SNP) | VAF 64/202 reads (32%) | catalogued as COSV99669352; called by muse, mutect2, varscan2
- SLC7A1 | c.849G>A p.Q283= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1475671068, COSV101060252; called by muse, mutect2, varscan2
- SYNGR1 | c.528C>T p.A176= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs779373100, COSV100198429, COSV59560047; called by muse, mutect2, varscan2
- TAF5 | c.1954C>A p.R652= | Silent (SNP) | VAF 62/65 reads (95%) | catalogued as COSV100428282; called by muse, mutect2, varscan2
- TCTEX1D1 | c.15C>T p.D5= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs768779294, COSV99259315; called by muse, mutect2, varscan2
- ZNF282 | c.1944C>T p.H648= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs748402894, COSV100021809; called by muse, mutect2, varscan2
